TCGA case TCGA-SH-A7BD — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: Papworth Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/83b97927-a1be-441a-97a1-4363e1f2d530

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United Kingdom; Age at index: 68 years; Vital status: Dead; Days to death: 459 days (1.3 years).

Diagnoses (2)
1. Epithelioid mesothelioma, malignant (the primary disease): ICD-O-3 morphology code: 9052/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 68.5 years (25,019 days); Year of diagnosis: 2012; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R2.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Pemetrexed; Days to treatment start: 58 days; Days to treatment end: 163 days; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Pemetrexed; Days to treatment start: 388 days (1.1 years); Days to treatment end: 429 days (1.2 years); Treatment outcome: Partial Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 455 days (1.2 years); Days to treatment end: 458 days (1.3 years); Treatment dose: 16 Gy; Treatment outcome: Partial Response; Number of fractions: 4; Treatment anatomic sites: Regional Site.
   Recorded as not given: Pleurodesis, NOS, prior to procurement.
2. Metastasis of diagnosis 1 (Epithelioid mesothelioma, malignant), site: Thorax, NOS. Age at diagnosis: 69.0 years (25,219 days); Days to diagnosis: 200 days; Prior treatment: Yes.

Follow-up (4 entries)
- Day 200 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Thorax, NOS; Days to recurrence: 200 days.
- Day 200 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Thorax, NOS; Days to progression: 200 days.
- Days to follow up: 459 days (1.3 years); Disease response: With Tumor.
- ECOG performance status: 3; Timepoint: Post Adjuvant Therapy.

Molecular and laboratory tests
- Creatinine 109 mg/dL [Blood test normal range lower: 35; Blood test normal range upper: 125].

Exposures
- Occupation type: Engineering Professionals (excluding Electrotechnology).
- Exposure type: Asbestos; Exposure source: Occupational.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-SH-A7BD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 20 mg.
  Slide TCGA-SH-A7BD-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 30; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-SH-A7BD-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-SH-A7BD-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: With tumor; History asbestos exposure: Yes; Primary occupation: Other, please specify; Occupation primary: Engineer; Performance status timing: Post-Adjuvant Therapy.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Epithelioid mesothelioma.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 459 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 459 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 200 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-SH-A7BD-01A-11D-A34B-01): tumor purity 0.88, ploidy 1.88, whole-genome doublings 0.
